Somatic mutation profile of tumor specimen TCGA-14-0736-02A (aliquot TCGA-14-0736-02A-01D-2280-08) from TCGA case TCGA-14-0736, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.9 years (18,219 days).
Specimen TCGA-14-0736-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05ed149e-a92d-4ed8-a7d6-3b43d6164c14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0736-10C (Blood Derived Normal), aliquot TCGA-14-0736-10C-01D-2280-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e447a67-1599-4a0d-9311-cb9651f15bdd

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Nonsense Mutation 4, Splice Site 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.492+2del p.X164_splice | Splice Site (DEL) | VAF 4/24 reads (17%) | catalogued as rs1060500124, CD115958, CS982333, COSV64288576, COSV64288590; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ACVRL1 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101187896; called by muse, mutect2, varscan2
- BPIFB2 | c.554A>T p.N185I | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99401373; called by muse, mutect2, varscan2
- CALD1 | c.216C>T p.N72= | Splice Region (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100724202; called by muse, mutect2, varscan2
- CASP2 | c.1164G>C p.E388D | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100130987; called by muse, mutect2
- CDIP1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99566527; called by muse, mutect2, varscan2
- CHST8 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.603); catalogued as COSV52861724, COSV99381045; called by muse, mutect2, varscan2
- CPA6 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52733115; called by muse, mutect2
- CTCF | c.1623C>A p.H541Q | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99865228; called by muse, mutect2, varscan2
- ENDOD1 | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99566529; called by muse, mutect2
- ENTPD4 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 47/127 reads (37%) | catalogued as COSV62268801; called by muse, mutect2, varscan2
- FCRL3 | c.1520T>C p.L507P | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100943167; called by muse, mutect2, varscan2
- FHOD3 | c.3434C>T p.S1145L (on ENST00000359247 / NM_001281739.3; = p.S1162L on NM_025135.5) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs756604100, COSV99940946; called by muse, mutect2, varscan2
- FLG | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 145/763 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100911522, COSV64241780; called by muse, mutect2, varscan2
- GDAP1L1 | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV100697553; called by muse, mutect2, varscan2
- HERC2 | c.11911G>A p.A3971T | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs778293898, COSV99873257; called by muse, mutect2
- KDM3B | c.3060G>A p.W1020* | Nonsense Mutation (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100069500; called by muse, mutect2
- KRT15 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1336068521, COSV54179879; called by muse, mutect2, varscan2
- KRT6A | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs754716072, COSV58104134; called by muse, mutect2
- LGALS3BP | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370418817; called by muse, mutect2, varscan2
- MYH1 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs750331285, COSV56844274, COSV56856511; called by muse, mutect2, varscan2
- MYO7A | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs748007093, COSV101289106, COSV101289115; called by muse, mutect2, varscan2
- MYOCD | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480273905, COSV100590200; called by muse, mutect2, varscan2
- NDRG1 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs199995009, COSV100105957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OPRK1 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as rs745533525, COSV55569565; called by muse, mutect2, varscan2
- OR2V2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100080096; called by muse, mutect2, varscan2
- PRDM1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs775868156, COSV100958741; called by muse, mutect2, varscan2
- RBM47 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs781033383, COSV55937302, COSV99921054; called by muse, mutect2, varscan2
- RORB | c.546C>A p.D182E (on ENST00000396204 / NM_001365023.1; = p.D171E on NM_006914.4) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV100974313; called by muse, mutect2
- SUFU | c.454+1G>T p.X152_splice | Splice Site (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100883019, COSV104425316; called by muse, mutect2, varscan2
- TRIM26 | c.903G>C p.Q301H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV101443936; called by muse, mutect2
- TRPC1 | c.2325A>G p.I775M (on ENST00000476941 / NM_001251845.2; = p.I741M on NM_003304.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs762854141, COSV99858663; called by muse, mutect2, varscan2
- UNC13A | c.3061C>T p.R1021W | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1338203040, COSV99408163; called by muse, mutect2
- ACTRT1 | c.309A>G p.Q103= | Silent (SNP) | VAF 43/180 reads (24%) | catalogued as COSV100947574; called by muse, mutect2, varscan2
- CFAP57 | c.720C>T p.T240= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100993953, COSV65264226; called by muse, mutect2, varscan2
- DIDO1 | c.2205T>C p.P735= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs1314150072, COSV99825682; called by muse, mutect2
- ETFBKMT | c.486A>G p.R162= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1030470545, COSV99861512; called by muse, mutect2, varscan2
- LRP2 | c.3606C>T p.G1202= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as rs759833611, COSV55542645; called by muse, mutect2, varscan2
- MUSK | c.1287G>A p.L429= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as COSV99504106; called by muse, mutect2, varscan2
- OR2T1 | c.655C>A p.R219= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100822302, COSV63542612; called by muse, mutect2, varscan2
- SYT12 | c.1044G>T p.P348= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV101210875; called by muse, mutect2, varscan2
- TEX15 | c.7929A>G p.P2643= (on ENST00000256246; = p.P3026= on NM_001350162.2) | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs981460790, COSV99821273; called by muse, mutect2, varscan2
- URB1 | c.664+1257T>A | Intron (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100784061; called by muse, mutect2
